CCDI case PBBRAK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a98d65d7-4ebc-4782-b0e7-a6f2befd92ad

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Atypical choroid plexus papilloma: ICD-O-3 morphology code: 9390/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.2 years (1,551 days).

Biospecimens (2 samples)
- Sample 0DER07: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DER09: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
